Somatic mutation profile of tumor specimen 0f757044-9bc8-4ed4-90f3-e0a49a (aliquot 0f757044-9bc8-4ed4-90f3-e0a49a_D6_1) from CPTAC case 11CO010, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 0f757044-9bc8-4ed4-90f3-e0a49a: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7166711c-6f2d-407f-9734-b89f58341250.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6a61fdfd-3d84-425d-8c72-ce8302 (Blood Derived Normal), aliquot 6a61fdfd-3d84-425d-8c72-ce8302_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db68e9e2-2de6-44bc-8758-9d7d8649efff

The open-access MAF lists 123 somatic variants for this specimen: 83 protein-altering or splice-affecting, 27 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 27, Intron 6, Nonsense Mutation 6, Splice Region 3, 5'UTR 3, Frame Shift Del 2, RNA 1, Frame Shift Ins 1, 5'Flank 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 116/260 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.3443C>T p.T1148M | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs775064149, COSV57009673; called by muse, mutect2, varscan2
- AJAP1 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs1018927688; called by muse, mutect2, varscan2
- ARHGEF1 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV61529762; called by muse, mutect2, varscan2
- ARVCF | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs570091802; called by muse, mutect2
- ASH2L | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1246629078, COSV51698994; called by muse, mutect2, varscan2
- C7orf26 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV60419173; called by muse, mutect2, varscan2
- CCDC186 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV65161613; called by muse, mutect2, varscan2
- CEACAM20 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 56/352 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs374925599; called by muse, mutect2, varscan2
- CKAP5 | c.5641G>A p.E1881K (on ENST00000529230 / NM_001008938.4; = p.E1821K on NM_014756.3) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs531082476, COSV56371019; called by muse, mutect2, varscan2
- CLCN1 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1473430259, COSV58368059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNPH1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773395453, COSV52729110; called by muse, mutect2, varscan2
- EPC2 | c.1795G>C p.A599P | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV51541384; called by muse, mutect2, varscan2
- EPHB6 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 35/345 reads (10%) | catalogued as rs528051156, COSV67420521; called by muse, mutect2, varscan2
- EVC2 | c.545C>G p.T182R | Missense Mutation (SNP) | VAF 105/368 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs747082570; called by muse, mutect2, varscan2
- GLI2 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 72/732 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs1452917426; called by muse, mutect2
- GRK1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 103/470 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755707527, COSV59553806; called by muse, mutect2, varscan2
- GRM6 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs879403706; called by muse, mutect2
- IL1R1 | c.1477A>G p.I493V | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs1364335395; called by muse, mutect2, varscan2
- KCND3 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 73/519 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs780219355, COSV56191082; called by muse, mutect2, varscan2
- KLK8 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs56296296; called by muse, mutect2, varscan2
- LAS1L | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV56707682; called by muse, mutect2
- LRRC32 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs145077681; called by muse, mutect2, varscan2
- MAP1S | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as rs1220348720; called by muse, mutect2, varscan2
- MUC5AC | c.14162G>A p.R4721H | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781484473, COSV100611650; called by muse, mutect2, varscan2
- NECAP1 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV60249989; called by muse, mutect2, varscan2
- PASK | c.2474C>T p.P825L | Missense Mutation (SNP) | VAF 148/492 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs774797247; called by muse, mutect2, varscan2
- PCDHA3 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 124/670 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as rs782438161, COSV63543307; called by muse, mutect2, varscan2
- PCDHA5 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 123/912 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65351320; called by muse, mutect2, varscan2
- PLEKHG4B | c.3799C>T p.R1267C (on ENST00000283426; = p.R1623C on NM_052909.5) | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as rs765464969; called by muse, mutect2, varscan2
- POLN | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 26/156 reads (17%) | catalogued as rs770351758; called by muse, mutect2, varscan2
- PRMT5 | c.577del p.R193Gfs*45 | Frame Shift Del (DEL) | VAF 50/157 reads (32%) | catalogued as COSV53547231; called by mutect2, pindel, varscan2
- RARRES1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV52963669; called by muse, mutect2, varscan2
- RASAL3 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.598); catalogued as rs781117253; called by muse, mutect2, varscan2
- RPS6KA4 | c.1576G>A p.V526M | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767134558; called by muse, mutect2, varscan2
- RPS6KA6 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1162253294; called by muse, mutect2, varscan2
- SOX11 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs1471365952, COSV100431028; called by muse, mutect2
- SPEG | c.9586C>T p.R3196* | Nonsense Mutation (SNP) | VAF 85/242 reads (35%) | catalogued as rs746906014, COSV56664366; called by muse, mutect2, varscan2
- TENM2 | c.8038C>T p.R2680C (on ENST00000518659 / NM_001122679.2; = p.R2441C on NM_001080428.3) | Missense Mutation (SNP) | VAF 130/331 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776846962; called by muse, mutect2, varscan2
- TEX13B | c.171C>A p.S57R | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.236); catalogued as COSV57203242; called by muse, mutect2, varscan2
- TRIM55 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs759175517; called by muse, mutect2, varscan2
- TRMT1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs1166772264; called by muse, mutect2, varscan2
- TTN | c.68225C>T p.S22742L (on ENST00000591111; = p.S15318L on NM_003319.4) | Missense Mutation (SNP) | VAF 50/258 reads (19%) | PolyPhen possibly damaging (0.482); catalogued as rs368415251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.4663G>T p.G1555C | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); catalogued as CM128001, COSV100239895, COSV56445304; called by muse, mutect2, varscan2
- ZNF879 | c.255C>T p.L85= | Splice Region (SNP) | VAF 28/134 reads (21%) | catalogued as rs566204932; called by muse, mutect2, varscan2
- ADGRL3 | c.65A>C p.H22P | Missense Mutation (SNP) | VAF 44/391 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- APC | c.1634dup p.S546Efs*14 | Frame Shift Ins (INS) | VAF 22/63 reads (35%) | called by mutect2, varscan2
- BPIFB4 | c.420G>C p.R140S | Missense Mutation (SNP) | VAF 54/996 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- CD81 | c.280-8G>A | Splice Region (SNP) | VAF 71/563 reads (13%) | called by muse, mutect2, varscan2
- CETP | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 197/623 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- DBR1 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPF2 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- FOXD4 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 62/728 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FOXD4L1 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 134/544 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- FSCN1 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 55/351 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GOLGA6L10 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 36/606 reads (6%) | called by muse, mutect2
- GOLGA8Q | c.1771G>T p.E591* | Nonsense Mutation (SNP) | VAF 29/227 reads (13%) | called by muse, mutect2, varscan2
- HDX | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL22RA1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INO80C | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- IRF5 | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 130/288 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ4 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 166/402 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LAMA2 | c.6079C>T p.P2027S | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MCM9 | c.2233T>G p.F745V | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MFSD9 | c.150C>A p.Y50* | Nonsense Mutation (SNP) | VAF 33/221 reads (15%) | called by muse, mutect2, varscan2
- NCF2 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PGBD4 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PIP5K1A | c.486G>A p.L162= (on ENST00000368888 / NM_001135638.2; = p.L149= on NM_003557.3) | Splice Region (SNP) | VAF 34/222 reads (15%) | called by muse, mutect2, varscan2
- PLOD3 | c.2041C>G p.H681D | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PRAMEF7 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- RAN | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- RAPGEFL1 | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RBM15 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGMB | c.362G>A p.C121Y (on ENST00000513185 / NM_001366508.1; = p.C162Y on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.17A>T p.K6M | Missense Mutation (SNP) | VAF 31/377 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- SLC39A12 | c.1682C>A p.A561E (on ENST00000377369 / NM_001145195.2; = p.A524E on NM_152725.3) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TGIF1 | c.533_534del p.T178Rfs*23 (on ENST00000330513 / NM_001374396.1; = p.T198Rfs*23 on NM_003244.4) | Frame Shift Del (DEL) | VAF 160/422 reads (38%) | called by pindel, varscan2
- TMEM39B | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TTC27 | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- U2AF1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZFYVE27 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 161/382 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- ZNF446 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 128/446 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF606 | c.1844A>T p.E615V | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); called by muse, mutect2
- ABHD15 | c.477G>A p.V159= | Silent (SNP) | VAF 33/276 reads (12%) | called by muse, mutect2, varscan2
- ACSM5 | c.1101C>T p.Y367= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as rs369835056; called by muse, mutect2, varscan2
- ADAD2 | c.741G>A p.P247= (on ENST00000315906 / NM_001145400.2; = p.P329= on NM_139174.4) | Silent (SNP) | VAF 37/404 reads (9%) | catalogued as rs374108586; called by muse, mutect2
- ART4 | c.885A>T p.I295= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- BRD2 | c.2262C>A p.P754= | Silent (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- BTNL3 | c.105C>T p.D35= | Silent (SNP) | VAF 61/206 reads (30%) | catalogued as rs183021703; called by muse, mutect2, varscan2
- CDK11B | c.1822C>T p.L608= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as rs368408810; called by muse, mutect2, varscan2
- DCANP1 | c.384C>T p.A128= | Silent (SNP) | VAF 51/233 reads (22%) | called by muse, mutect2, varscan2
- DGCR6L | c.495C>T p.Y165= | Silent (SNP) | VAF 95/472 reads (20%) | catalogued as rs752013195; called by muse, mutect2, varscan2
- DNASE1L3 | c.600G>A p.K200= | Silent (SNP) | VAF 23/166 reads (14%) | called by muse, mutect2, varscan2
- FPR1 | c.309C>T p.T103= | Silent (SNP) | VAF 120/459 reads (26%) | called by muse, mutect2
- FREM2 | c.9306C>T p.L3102= | Silent (SNP) | VAF 104/480 reads (22%) | called by muse, mutect2, varscan2
- GEMIN5 | c.3312C>T p.A1104= | Silent (SNP) | VAF 32/174 reads (18%) | called by muse, mutect2, varscan2
- INPP5A | c.894C>T p.N298= | Silent (SNP) | VAF 92/212 reads (43%) | catalogued as rs569271876, COSV61254211; called by muse, mutect2, varscan2
- IQGAP2 | c.624C>T p.S208= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs958792736, COSV99169246; called by muse, mutect2, varscan2
- MEGF8 | c.5028T>G p.S1676= (on ENST00000251268 / NM_001271938.2; = p.S1609= on NM_001410.3) | Silent (SNP) | VAF 52/125 reads (42%) | called by muse, mutect2, varscan2
- MGAT5B | c.2334C>T p.R778= (on ENST00000569840 / NM_001199172.2; = p.R776= on NM_144677.3) | Silent (SNP) | VAF 103/343 reads (30%) | catalogued as rs776417904; called by muse, mutect2, varscan2
- OR10H2 | c.45C>T p.V15= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as rs769258378; called by muse, mutect2, varscan2
- PPP1R26 | c.1125C>T p.Y375= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs769824028, COSV63355308; called by muse, mutect2, varscan2
- SBNO2 | c.2460C>T p.R820= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as rs376700739; called by muse, mutect2
- SCAP | c.1731C>T p.F577= | Silent (SNP) | VAF 21/186 reads (11%) | called by muse, mutect2, varscan2
- SETD1A | c.3813G>A p.L1271= | Silent (SNP) | VAF 99/310 reads (32%) | catalogued as rs372313005; called by muse, mutect2, varscan2
- STX11 | c.666C>T p.R222= | Silent (SNP) | VAF 99/544 reads (18%) | catalogued as rs768064993, COSV100845483; called by muse, mutect2, varscan2
- SULF1 | c.2058G>A p.E686= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV52689000; called by muse, mutect2, varscan2
- TECTA | c.3858G>A p.P1286= | Silent (SNP) | VAF 284/579 reads (49%) | catalogued as rs570135101, COSV99879088; called by muse, mutect2, varscan2
- TKTL1 | c.381C>T p.G127= | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- UNC13D | c.453C>T p.P151= | Silent (SNP) | VAF 54/389 reads (14%) | catalogued as rs138997390; called by muse, mutect2, varscan2
- AC009779.3 | c.*2567G>A | 3'UTR (SNP) | VAF 72/434 reads (17%) | called by muse, mutect2, varscan2
- ALMS1P1 | n.835T>C | RNA (SNP) | VAF 82/210 reads (39%) | catalogued as rs575924517; called by muse, mutect2, varscan2
- FXYD3 | c.-59C>T | 5'UTR (SNP) | VAF 101/308 reads (33%) | catalogued as rs960744663, COSV59743050; called by muse, mutect2, varscan2
- GTPBP1 | c.-10G>A | 5'UTR (SNP) | VAF 5/22 reads (23%) | catalogued as rs868200945; called by muse, mutect2, varscan2
- HAMP | c.151-22C>G | Intron (SNP) | VAF 16/618 reads (3%) | called by muse, mutect2
- HEG1 | c.1589-904C>T | Intron (SNP) | VAF 25/173 reads (14%) | catalogued as rs534244485, COSV104409012; called by muse, mutect2, varscan2
- MAP3K1 | c.4257+9C>T | Intron (SNP) | VAF 133/301 reads (44%) | called by muse, mutect2, varscan2
- MED15 | c.68+11244C>G | Intron (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- RBFOX1 | c.414+166453G>A | Intron (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- RNU6-713P | chr12:40550136 C>A | 3'Flank (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- TTC39A | c.999+163G>C | Intron (SNP) | VAF 120/284 reads (42%) | called by muse, mutect2, varscan2
- WASHC2A | chr10:50067908 T>C | 5'Flank (SNP) | VAF 29/156 reads (19%) | catalogued as rs1483722636; called by muse, mutect2, varscan2
- ZNF292 | c.-4G>A | 5'UTR (SNP) | VAF 38/195 reads (19%) | called by muse, mutect2, varscan2
